Somatic mutation profile of tumor specimen TCGA-B3-4103-01A (aliquot TCGA-B3-4103-01A-01D-1458-08) from TCGA case TCGA-B3-4103, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 56.7 years (20,708 days).
Specimen TCGA-B3-4103-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 631160a2-c468-4b46-a7f3-2b6d4a433864.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-4103-10A (Blood Derived Normal), aliquot TCGA-B3-4103-10A-01D-1458-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7b9b13b-3375-4ea0-a5cd-477c6ed5a158

The open-access MAF lists 55 somatic variants for this specimen: 42 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 35, Silent 13, Frame Shift Del 4, Nonsense Mutation 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG4 | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV56645323; called by muse, mutect2, varscan2
- ADAMTS17 | c.1750G>A p.G584S | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs1434025252; called by muse, mutect2, varscan2
- ARHGAP24 | c.2063A>G p.D688G (on ENST00000395184 / NM_001025616.3; = p.D595G on NM_031305.3) | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs768323502; called by muse, mutect2, varscan2
- ATP1A1 | c.2282G>C p.G761A | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs11540954; called by muse, mutect2, varscan2
- EEF2 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58580704; called by muse, mutect2, varscan2
- ITPRIP | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1356228310; called by muse, mutect2, varscan2
- SELE | c.781del p.S261Afs*18 | Frame Shift Del (DEL) | VAF 81/243 reads (33%) | catalogued as COSV60978019; called by mutect2, pindel, varscan2
- ABRA | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- AC011462.1 | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- ACE | c.1966T>C p.Y656H | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANGEL1 | c.730_739del p.Q244* | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | called by mutect2, pindel, varscan2
- AP4M1 | c.176T>C p.I59T | Missense Mutation (SNP) | VAF 53/252 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- ARF5 | c.124A>G p.I42V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ASGR1 | c.11A>C p.E4A | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ATP1B1 | c.505T>C p.Y169H | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BMPR1B | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP350 | c.623del p.N208Ifs*5 | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- CLUH | c.911G>A p.R304K (on ENST00000435359; = p.R342K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CYHR1 | c.93G>C p.E31D | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- DAZAP1 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DST | c.2702T>G p.I901S (on ENST00000361203 / NM_001374722.1; = p.I575S on NM_001723.6) | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EP300 | c.6968_6970del p.P2323del | In Frame Del (DEL) | VAF 32/125 reads (26%) | called by mutect2, pindel, varscan2
- FAM135A | c.1889T>A p.M630K (on ENST00000370479 / NM_001351599.1; = p.M417K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBN3 | c.3500del p.D1167Afs*21 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel, varscan2
- GABRG2 | c.1227A>T p.K409N (on ENST00000361925 / NM_001375343.1; = p.K369N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HCFC1R1 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2
- IFT140 | c.2245C>A p.H749N | Missense Mutation (SNP) | VAF 146/531 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ITGB5 | c.1315G>T p.E439* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- JAG2 | c.536A>G p.K179R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- KCNH7 | c.2813T>C p.I938T | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG2 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 63/326 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K14 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MINDY3 | c.567A>T p.L189F | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- MRPL13 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFAS | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIPOX | c.114+1dup | Frame Shift Ins (INS) | VAF 64/170 reads (38%) | called by pindel, varscan2
- SLC5A3 | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 100/280 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMC3 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- TMEM37 | c.386T>C p.I129T | Missense Mutation (SNP) | VAF 116/432 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNFSF8 | c.696T>G p.N232K | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNKS2 | c.1352T>C p.L451P | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF627 | c.1306G>T p.V436L | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP251 | c.2982T>C p.I994= | Silent (SNP) | VAF 48/136 reads (35%) | called by muse, mutect2, varscan2
- CLOCK | c.2469T>A p.S823= | Silent (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.4314A>T p.I1438= | Silent (SNP) | VAF 50/174 reads (29%) | called by muse, mutect2, varscan2
- EIF3G | c.6T>C p.P2= | Silent (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- FRMD6 | c.912G>T p.T304= (on ENST00000344768 / NM_001267046.2; = p.T296= on NM_152330.4) | Silent (SNP) | VAF 14/149 reads (9%) | called by muse, mutect2
- GOLT1A | c.9C>A p.S3= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ITGB5 | c.1314G>A p.T438= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs773136191; called by muse, mutect2, varscan2
- NRROS | c.1326C>T p.P442= | Silent (SNP) | VAF 180/436 reads (41%) | called by muse, mutect2, varscan2
- PCYT1A | c.351C>T p.L117= | Silent (SNP) | VAF 60/230 reads (26%) | called by muse, mutect2, varscan2
- SUSD2 | c.861C>A p.A287= | Silent (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- TTLL1 | c.1041G>C p.L347= | Silent (SNP) | VAF 13/290 reads (4%) | called by muse, mutect2
- UGT2B7 | c.1335A>G p.L445= | Silent (SNP) | VAF 63/240 reads (26%) | called by muse, mutect2, varscan2
- VPS4B | c.1254A>G p.L418= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs200045966; called by muse, mutect2, varscan2
